PECGS case C083-000010 — USC PE-CGS: Optimizing Engagement of Hispanic Colorectal Cancer Patients in Cancer Genomic Characterization Studies (PECGS-COPECC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Adenomas and Adenocarcinomas; Primary site: Rectum. Index date: not stated by GDC for this case (day counts are relative to an unstated reference).
https://portal.gdc.cancer.gov/cases/87e89e48-a1ef-43d0-8799-178483cc1f98

Demographics
Sex at birth: male; Race: white; Ethnicity: hispanic or latino; Age at index: 46 years; Year of birth: 1975; Education level: College Degree.

Diagnoses (1)
1. Adenocarcinoma, NOS: ICD-O-3 morphology code: 8140/3; Tissue or organ of origin: Rectum, NOS; Age at diagnosis: 45.7 years (16,692 days); AJCC clinical stage: Stage IVB; AJCC pathologic stage: Stage IVB; Progression or recurrence: yes; Days to last follow up: 84 days.

Other clinical attributes
- BMI: 32.89.

Exposures
- Tobacco smoking status: Current Reformed Smoker for < or = 15 yrs; Pack years smoked: 2.25; Alcohol history: Yes.

Biospecimens (2 samples)
- Sample C083-000010_Germline: Tissue type: Normal; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample C083-000010_Tumor: Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
